Gene-level copy-number profile of tumor specimen TCGA-A2-A0T1-01A from TCGA case TCGA-A2-A0T1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 55.4 years (20,227 days).
Specimen TCGA-A2-A0T1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e8889068-b216-4662-816f-b8e712b61ec7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0T1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 822 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/24ead709-4eb1-4937-887f-fe2b9e0d2e4d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 916; copy number 2: 9,762; copy number 3: 26,322; copy number 4: 15,240; copy number 5: 4,140; copy number 6: 800; copy number 7: 313; copy number 8: 529; copy number 9: 361; copy number 10: 16; copy number 11: 111; copy number 12: 268; copy number 13: 55; copy number 14: 142; copy number 16: 238; copy number 17: 24; copy number 18: 154; copy number 20: 89; copy number 21: 17; copy number 23: 40; copy number 24: 28; copy number 25: 8; copy number 26: 27; copy number 28: 53; copy number 29: 6; copy number 30: 8; copy number 31: 82; copy number 38: 23; copy number 42: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0T1-01A-21D-A087-01): tumor purity 0.19, ploidy 3.49, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,621 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,573,747–158,357,553, 25 genes, copy number 8: FCRL4, AL135929.2, AL135929.1, FCRL3, AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, SMIM42, LINC01704, ELL2P1, CD1D, AL138899.2, AL138899.1, CD1A, HMGN1P5, CD1C, CD1B, CD1E.
- chr1:158,605,268–164,980,137, 208 genes, copy number 7–24 (broad region; genes not listed).
- chr2:125,665,331–126,702,942, 12 genes, copy number 7: AC097499.2, LINC01889, AC097499.1, LINC01941, AC142116.2, AC023347.1, SLC6A14P3, YWHAZP2, AC013474.2, GYPC, AC013474.1, RNU6-675P.
- chr4:69,182,100–77,702,803, 170 genes, copy number 10–20 (within-gene range 5–20) (broad region; genes not listed).
- chr5:24,729,379–24,910,695, 8 genes, copy number 7: AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA.
- chr5:28,548,135–28,809,291, 1 gene, copy number 7 (within-gene range 2–7): AC008825.1.
- chr5:28,808,538–29,217,115, 10 genes, copy number 7 (within-gene range 2–7): AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3.
- chr5:36,098,407–37,377,971, 28 genes, copy number 9–17 (within-gene range 5–17): LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1.
- chr5:38,682,581–39,424,868, 10 genes, copy number 8 (within-gene range 4–8): OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9.
- chr5:41,142,116–41,261,438, 1 gene, copy number 13 (within-gene range 5–13): C6.
- chr5:41,585,882–45,895,970, 72 genes, copy number 8–14 (broad region; genes not listed).
- chr7:158,532,718–159,030,195, 11 genes, copy number 7: MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689.
- chr8:46,028,804–119,673,453, 1,068 genes, copy number 8–31 (broad region; genes not listed).
- chr8:125,648,327–126,008,930, 1 gene, copy number 9 (within-gene range 6–9): AC016074.2.
- chr8:125,859,721–134,979,279, 129 genes, copy number 7–17 (broad region; genes not listed).
- chr8:135,859,369–137,092,183, 3 genes, copy number 11 (within-gene range 5–11): LINC02055, AC103955.1, AC023781.1.
- chr8:139,727,725–141,786,313, 37 genes, copy number 9 (within-gene range 5–9): TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1, AC025839.1, MIR1302-7.
- chr9:115,888,169–119,974,322, 31 genes, copy number 7–9 (within-gene range 6–9): LINC00474, AL691426.1, PAPPA, PAPPA-AS2, AL137024.1, PAPPA-AS1, ASTN2, ASTN2-AS1, AL133284.1, TRIM32, AL157829.1, RPL10P3, SNORA70C, RN7SKP128, RN7SKP125, AL445644.1, AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1, TPT1P9, AL355592.1, LINC02578, TUBB4BP6, BRINP1, AC006288.1, LINC01613, AL441989.1.
- chr9:122,144,058–122,229,626, 3 genes, copy number 8: NDUFA8, MORN5, LHX6.
- chr9:123,736,437–127,223,166, 65 genes, copy number 7–9 (broad region; genes not listed).
- chr17:35,400,878–35,726,413, 27 genes, copy number 26: AC060766.6, AC060766.4, AC060766.7, AC060766.5, AC060766.1, SLFN12, SLFN13, AC015911.4, SLFN12L, AC015911.7, SLFN12L, AC015911.5, E2F3P1, TAF5LP1, AC015911.3, TOMM20P2, AC015911.9, AC015911.2, SLFN14, AC015911.6, AC015911.8, AC015911.1, SNHG30, SNORD7, PEX12, AP2B1, AC004134.1.
- chr17:38,195,703–40,017,813, 81 genes, copy number 23–42 (broad region; genes not listed).
- chr17:40,026,332–40,027,645, 2 genes, copy number 42: MIR6884, SNORD124.
- chr17:62,910,021–65,641,033, 106 genes, copy number 7–12 (broad region; genes not listed).
- chr17:65,644,308–65,655,395, 2 genes, copy number 7: AC004805.3, AC004805.2.
- chr17:80,940,418–83,095,122, 143 genes, copy number 18–29 (broad region; genes not listed).
- chr21:14,216,130–15,880,069, 28 genes, copy number 8: RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1, AF127936.1, POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP.
- chr21:16,035,413–16,035,509, 1 gene, copy number 8: RNU6-426P.
- chr21:30,089,717–31,063,168, 50 genes, copy number 7: AF096876.1, CLDN17, LINC00307, CLDN8, RPL8P2, KRTAP24-1, KRTAP25-1, KRTAP26-1, KRTAP27-1, KRTAP23-1, KRTAP13-6P, KRTAP13-2, MIR4327, KRTAP13-1, KRTAP13-3, KRTAP13-4, KRTAP13-5P, KRTAP15-1, KRTAP19-1, KRTAP19-2, KRTAP19-3, KRTAP19-4, KRTAP19-5, KRTAP19-9P, KRTAP19-10P, AP000567.1, KRTAP19-11P, KRTAP19-6, KRTAP19-7, KRTAP22-2, KRTAP6-3, KRTAP6-2, KRTAP22-1, KRTAP6-1, KRTAP20-1, KRTAP20-4, KRTAP20-2, KRTAP20-3, KRTAP21-3, KRTAP21-4P, KRTAP21-2, KRTAP21-1, AP000244.1, KRTAP8-2P, KRTAP8-3P, KRTAP8-1, KRTAP7-1, KRTAP11-1, KRTAP19-8, UBE3AP2.
- chr21:36,943,267–40,847,158, 77 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr21:41,141,493–46,665,124, 211 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 916. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
